Somatic mutation profile of tumor specimen TCGA-EJ-A7NN-01A (aliquot TCGA-EJ-A7NN-01A-11D-A33T-08) from TCGA case TCGA-EJ-A7NN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.6 years (22,499 days).
Specimen TCGA-EJ-A7NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 076b9d50-77a5-4a56-acb6-7b38360c4b48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A7NN-10A (Blood Derived Normal), aliquot TCGA-EJ-A7NN-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e362116-64c7-40f1-9c0c-efb8e0f60822

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 24, Silent 6, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.3398G>A p.R1133K | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV100383310, COSV100383702; called by muse, mutect2, varscan2
- ALDH1A3 | c.849dup p.K284Efs*11 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | catalogued as rs758955164; called by mutect2, varscan2
- ATP13A1 | c.3313A>G p.I1105V | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs752148086, COSV99179393; called by muse, mutect2, varscan2
- CCDC141 | c.3821A>T p.D1274V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99837126; called by muse, mutect2, varscan2
- CMA1 | c.288A>C p.Q96H | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99157560; called by muse, mutect2, varscan2
- COL21A1 | c.1952C>T p.T651I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99779450; called by muse, mutect2, varscan2
- CPT1C | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.463); catalogued as COSV99773547; called by muse, mutect2, varscan2
- CYTIP | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202198683, COSV99938824; called by muse, mutect2, varscan2
- DDI1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs114046986; called by muse, mutect2, varscan2
- DGKI | c.2115C>A p.S705R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.677); catalogued as COSV99934690; called by muse, mutect2
- DTNB | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99977683; called by muse, mutect2, varscan2
- EPS15 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs368190737; called by muse, mutect2
- GAL3ST3 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1235317186, COSV61749295; called by muse, mutect2, varscan2
- IGSF10 | c.3248G>A p.S1083N | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as COSV99183928; called by muse, mutect2, varscan2
- ITPRIP | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs760892346, COSV99532656; called by muse, mutect2, varscan2
- NEU2 | c.202-2A>C p.X68_splice | Splice Site (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99290655; called by muse, mutect2, varscan2
- OR51Q1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs750405873, COSV56179937; called by muse, mutect2, varscan2
- PCDHB10 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1554284424, COSV99504679; called by muse, mutect2, varscan2
- PCSK2 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99360173; called by muse, mutect2, varscan2
- PDE6D | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.303); catalogued as rs758019119, COSV99807914; called by muse, mutect2, varscan2
- QRICH2 | c.4803C>G p.H1601Q | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99429457; called by muse, mutect2, varscan2
- SLC31A1 | c.8A>T p.H3L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100951933; called by muse, mutect2, varscan2
- TECTA | c.4511G>A p.R1504H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV99880651; called by muse, mutect2, varscan2
- TPR | c.4181A>G p.N1394S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV100824099; called by muse, mutect2, varscan2
- ZNF33B | c.2210C>A p.A737D | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.419); catalogued as COSV100847741, COSV100847832; called by muse, mutect2, varscan2
- ZNF491 | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100021991; called by muse, mutect2, varscan2
- FCGBP | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DSCC1 | c.513A>G p.Q171= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100558373; called by muse, mutect2, varscan2
- HMCN1 | c.507T>C p.F169= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99632397; called by muse, mutect2, varscan2
- IRF7 | c.645G>A p.G215= (on ENST00000397566; = p.G202= on NM_001572.5) | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99212570; called by muse, mutect2
- LETM1 | c.1716G>A p.L572= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV100245530; called by muse, mutect2, varscan2
- LRFN2 | c.2202G>A p.A734= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs201948377, COSV100599736; called by muse, mutect2, varscan2
- PCDHA6 | c.1842G>A p.P614= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs1554132408, COSV65343085; called by muse, mutect2, varscan2
